Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LL, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LL-01A (Primary Tumor).

ICD-O-3

Carcinoma, Adrenal Cortical
8370/3

Site: ~~B~~ Adrenal Gland, cortex
C74.0

9w 2/6/13

Procedure: Right adrenalectomy and Right nephrectomy

Gross Description: Adrenal tumor is 172g; measuring 9 x 7 x 5cm. There is a 0.7cm nodule in the right kidney with granulomatous cells and gigantic cells; possibility of tuberculosis is raised.

Diagnosis: Adrenal cortical carcinoma. Weiss score = 7. No LN mets (+0/10). No invasion of renal artery. s/p cholecystectomy ---> chronic inflammatory changes.

ICD-O-3 Discrepancy		

W 1/16/13

QUALIFIED / 1/16/13

Source: NCI Genomic Data Commons file 1a9cd5a7-7f77-4fd0-a3f3-288f049912de (TCGA-OR-A5LL.A898F0C7-9596-4DF1-9784-CAACFAB672D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).